Somatic mutation profile of tumor specimen 1105224 (aliquot 7316UP-574-1105224) from CPTAC case C298152, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105224: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bce91e6-48ad-4071-b389-e89758bafcfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105208 (Blood Derived Normal), aliquot 7316UP-426-1105208; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3300c251-ca72-4440-b390-44840990a295

The open-access MAF lists 37 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, Nonsense Mutation 1, Intron 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs864622341, COSV64290156; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- USH2A | c.10450C>T p.R3484* | Nonsense Mutation (SNP) | VAF 51/135 reads (38%) | catalogued as rs111033379, CM080610, COSV56427899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs779902900, COSV60922721; called by muse, mutect2, varscan2
- CPAMD8 | c.1474G>A p.G492S (on ENST00000651564; = p.G445S on NM_015692.5) | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs574048580; called by muse, mutect2, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- MTHFR | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775829502, COSV100928224; called by muse, mutect2
- MUC5B | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs554624154; called by muse, mutect2, varscan2
- NPNT | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs778565408, COSV59753816; called by muse, mutect2, varscan2
- OBSCN | c.13361C>T p.T4454M | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs758896862, COSV52750133, COSV52751888; called by muse, varscan2
- PCLO | c.8125C>A p.H2709N | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV61653611; called by muse, mutect2, varscan2
- PLCG1 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814695; called by muse, mutect2, varscan2
- RELB | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as rs571786771, COSV55513078; called by muse, mutect2, varscan2
- RGS9 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 129/368 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs913010766, COSV52225932; called by muse, mutect2, varscan2
- SIPA1L3 | c.1345G>A p.V449M | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs370319919; called by muse, mutect2, varscan2
- TRPV6 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs775866936; called by muse, mutect2, varscan2
- WDR88 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as rs201611292; called by muse, mutect2, varscan2
- AKAP9 | c.5905C>A p.Q1969K (on ENST00000359028; = p.Q1937K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- BTN3A3 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EML3 | c.1074C>A p.F358L | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR52B4 | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PABPN1 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 100/407 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB5 | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRRAP | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADIPOQ | c.624C>T p.G208= | Silent (SNP) | VAF 81/142 reads (57%) | catalogued as rs200876636; called by muse, mutect2, varscan2
- APBB1 | c.30G>A p.S10= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs777578946; called by muse, mutect2
- CNTNAP2 | c.2037C>T p.A679= | Silent (SNP) | VAF 146/474 reads (31%) | catalogued as rs539741829, COSV62276109; called by muse, mutect2, varscan2
- CPNE4 | c.93G>A p.A31= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as rs368853915, COSV70193650; called by muse, mutect2, varscan2
- FAM83H | c.1992G>A p.K664= | Silent (SNP) | VAF 74/260 reads (28%) | called by muse, mutect2, varscan2
- FTCD | c.1479C>T p.G493= | Silent (SNP) | VAF 179/537 reads (33%) | catalogued as rs576503541, COSV52430942; called by muse, mutect2, varscan2
- GABRD | c.153C>T p.Y51= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as rs148496176; called by muse, mutect2, varscan2
- RAB6C | c.606C>T p.S202= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as COSV101308492; called by muse, mutect2, varscan2
- RIMS2 | c.588A>G p.L196= | Silent (SNP) | VAF 27/300 reads (9%) | called by muse, mutect2
- SF3B3 | c.1848C>A p.I616= | Silent (SNP) | VAF 50/143 reads (35%) | called by muse, mutect2, varscan2
- TSBP1 | c.495C>T p.H165= (on ENST00000617061; = p.P175S on NM_006781.5) | Silent (SNP) | VAF 56/187 reads (30%) | called by muse, mutect2
- AC058822.1 | c.1018-288066G>C | Intron (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- GNL1 | c.-940C>T | 5'UTR (SNP) | VAF 121/359 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.84G>A | RNA (SNP) | VAF 70/208 reads (34%) | catalogued as rs756590960; called by muse, mutect2, varscan2
